Somatic mutation profile of tumor specimen MMRF_2840_1_BM_CD138pos (aliquot MMRF_2840_1_BM_CD138pos_T1_KHS5U_L16578) from MMRF case MMRF_2840, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.5 years (21,749 days).
Specimen MMRF_2840_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb00fb6a-4788-4d3a-a1ab-b3e04766a6fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2840_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2840_1_PB_WBC_C2_KHS5U_L16672; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6ab4f5e-9b0a-4b4e-9370-7d73ed5af85f

The open-access MAF lists 51 somatic variants for this specimen: 17 protein-altering or splice-affecting, 11 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 17, Missense Mutation 15, Silent 11, Intron 6, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DGKK | c.964C>A p.P322T | Missense Mutation (SNP) | VAF 43/43 reads (100%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); catalogued as rs1557226979; called by muse, mutect2, varscan2
- SI | c.2101A>C p.T701P | Missense Mutation (SNP) | VAF 17/223 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52302401; called by muse, mutect2
- ABCA1 | c.3724A>G p.T1242A | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, varscan2
- ATPAF1 | c.589-2A>G p.X197_splice (on ENST00000574428; = p.X220_splice on NM_022745.4) | Splice Site (SNP) | VAF 10/10 reads (100%) | called by muse, mutect2, varscan2
- CAMK2D | c.1016A>C p.E339A | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- COL10A1 | c.76C>A p.Q26K | Missense Mutation (SNP) | VAF 11/292 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.095); called by muse, mutect2
- DSCAM | c.92T>C p.L31P | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.828); called by muse, mutect2
- FMN2 | c.1511A>G p.E504G | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HGF | c.44T>C p.V15A | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- INO80 | c.1629T>A p.D543E | Missense Mutation (SNP) | VAF 48/228 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MAGEB3 | c.344C>A p.T115K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MLYCD | c.334C>G p.L112V | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYO7A | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYSM1 | c.230C>G p.S77C | Missense Mutation (SNP) | VAF 23/23 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PMFBP1 | c.166-2A>G p.X56_splice | Splice Site (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- TRABD2B | c.206C>A p.P69Q | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ZNF644 | c.2825C>A p.A942E | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.024); called by muse, mutect2
- AFF3 | c.702T>C p.Y234= | Silent (SNP) | VAF 96/192 reads (50%) | called by muse, mutect2, varscan2
- ARHGAP39 | c.2893C>T p.L965= (on ENST00000276826 / NM_001308208.2; = p.L996= on NM_025251.2) | Silent (SNP) | VAF 18/18 reads (100%) | called by muse, mutect2, varscan2
- ATP8B3 | c.951G>C p.V317= | Silent (SNP) | VAF 24/72 reads (33%) | called by muse, mutect2, varscan2
- CCDC40 | c.2298C>T p.H766= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs754496723; called by muse, mutect2, varscan2
- CEACAM16 | c.636C>T p.S212= | Silent (SNP) | VAF 42/96 reads (44%) | catalogued as rs915972808, COSV101312622; called by muse, mutect2, varscan2
- HERC2 | c.13167A>C p.G4389= | Silent (SNP) | VAF 94/193 reads (49%) | called by muse, mutect2, varscan2
- NPC1L1 | c.1656C>T p.P552= | Silent (SNP) | VAF 25/145 reads (17%) | catalogued as COSV99212475; called by muse, mutect2, varscan2
- PRH1 | c.174C>T p.P58= | Silent (SNP) | VAF 54/92 reads (59%) | catalogued as rs779082796; called by muse, varscan2
- PTPRD | c.5364G>A p.K1788= | Silent (SNP) | VAF 70/84 reads (83%) | catalogued as COSV61927155, COSV61957097; called by muse, varscan2
- TNRC6A | c.3504A>G p.P1168= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as rs1323203563; called by muse, mutect2, varscan2
- VCL | c.1065G>A p.Q355= | Silent (SNP) | VAF 29/76 reads (38%) | called by muse, varscan2
- ADAMTS6 | c.*1808A>G | 3'UTR (SNP) | VAF 39/110 reads (35%) | called by muse, mutect2, varscan2
- AFF2 | c.*8057dup | 3'UTR (INS) | VAF 24/62 reads (39%) | catalogued as rs1285778391; called by mutect2, varscan2
- ATRAID | c.264+101C>G | Intron (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- BARD1 | c.*2174A>T | 3'UTR (SNP) | VAF 18/27 reads (67%) | called by muse, mutect2, varscan2
- BHLHE40 | c.*332C>T | 3'UTR (SNP) | VAF 8/204 reads (4%) | called by muse, mutect2
- CDH26 | c.*740G>T | 3'UTR (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- DTX3 | c.969-146C>T | Intron (SNP) | VAF 65/152 reads (43%) | called by muse, mutect2, varscan2
- GARRE1 | c.2688-52G>A | Intron (SNP) | VAF 12/37 reads (32%) | catalogued as rs1277748537; called by muse, mutect2, varscan2
- HSPB7 | c.*1206C>T | 3'UTR (SNP) | VAF 48/87 reads (55%) | catalogued as rs1216222500; called by muse, mutect2, varscan2
- NCAM2 | c.*5091C>A | 3'UTR (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- NKAPL | c.*148T>C | 3'UTR (SNP) | VAF 20/36 reads (56%) | called by muse, mutect2, varscan2
- OR2C3 | c.*1322G>T | 3'UTR (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- OR2C3 | c.*1321G>A | 3'UTR (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- PTPN21 | c.*2104T>G | 3'UTR (SNP) | VAF 34/62 reads (55%) | called by muse, mutect2, varscan2
- RBM11 | c.*815T>C | 3'UTR (SNP) | VAF 13/39 reads (33%) | catalogued as rs1402235270; called by muse, mutect2, varscan2
- S1PR2 | c.-43+746A>G | Intron (SNP) | VAF 52/166 reads (31%) | called by muse, mutect2, varscan2
- SPATA2 | c.*227T>C | 3'UTR (SNP) | VAF 25/44 reads (57%) | called by muse, mutect2, varscan2
- TGFB1 | c.713-65A>G | Intron (SNP) | VAF 91/288 reads (32%) | called by muse, mutect2, varscan2
- TICRR | c.*535A>C | 3'UTR (SNP) | VAF 16/63 reads (25%) | called by muse, mutect2, varscan2
- UBE2E2 | c.*128G>C | 3'UTR (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2, varscan2
- UBE2G2 | c.*2210T>C | 3'UTR (SNP) | VAF 29/55 reads (53%) | called by muse, mutect2, varscan2
- VIT | c.1013+594G>A | Intron (SNP) | VAF 31/45 reads (69%) | called by muse, mutect2, varscan2
- ZMAT3 | c.*1476T>A | 3'UTR (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2, varscan2
